Somatic mutation profile of tumor specimen TCGA-EX-A3L1-01A (aliquot TCGA-EX-A3L1-01A-11D-A21Q-09) from TCGA case TCGA-EX-A3L1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3; Age at diagnosis: 32.7 years (11,943 days).
Specimen TCGA-EX-A3L1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be8fb1c1-0de5-4648-b3ac-510c4d5bad42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A3L1-10A (Blood Derived Normal), aliquot TCGA-EX-A3L1-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b243b702-cf4b-4680-be40-a9a122f081cd

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 23, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5641C>T p.R1881* (on ENST00000272895 / NM_173076.3; = p.R1563* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs775127288, CM064932, COSV55964178; called by muse, mutect2, varscan2
- ADAMTS20 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67133929; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4310C>T p.S1437F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99720834, COSV99721816; called by muse, mutect2, varscan2
- AKT2 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100251824, COSV60909200; called by muse, mutect2, varscan2
- ANKRD13C | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032628; called by muse, mutect2, varscan2
- ANO6 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs955328263, COSV57663122; called by muse, mutect2, varscan2
- C16orf90 | c.358G>T p.G120C (on ENST00000399645 / NM_001353385.2; = p.G111C on NM_001080524.2) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV68714534; called by muse, mutect2, varscan2
- CNTRL | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53049054; called by muse, mutect2, varscan2
- COL12A1 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV59398955; called by muse, mutect2, varscan2
- EPN3 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1362425771, COSV52139814; called by muse, mutect2, varscan2
- GAS2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV53408894, COSV53412567; called by muse, mutect2, varscan2
- GHR | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs775194712, COSV50117116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF3C1 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100649660; called by muse, mutect2, varscan2
- HK2 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV51874470, COSV51876568; called by muse, mutect2, varscan2
- ITGA2 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV56861225, COSV99671484; called by muse, mutect2
- MUC16 | c.19142C>T p.S6381L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV67475666; called by muse, mutect2, varscan2
- NDE1 | c.976G>C p.E326Q (on ENST00000577101; = p.R298T on NM_017668.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.048); catalogued as COSV61273547; called by mutect2, varscan2
- NOTCH3 | c.5115G>A p.K1705= | Splice Region (SNP) | VAF 12/47 reads (26%) | catalogued as COSV54628816, COSV99657360; called by muse, mutect2, varscan2
- NQO1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57732111; called by muse, mutect2, varscan2
- OTOA | c.179G>C p.S60T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV53753646, COSV53757327; called by muse, mutect2, varscan2
- PTPRC | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV100723082, COSV61420840; called by muse, mutect2, varscan2
- SH3D19 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV58791446; called by muse, mutect2, varscan2
- SIM1 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs914427483, COSV53491182; called by muse, mutect2, varscan2
- TRIOBP | c.4549G>C p.E1517Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.551); catalogued as COSV60379800; called by muse, mutect2, varscan2
- ZNF2 | c.652G>A p.E218K (on ENST00000611147 / NM_001291605.2; = p.E205K on NM_021088.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs778835285, COSV54637374; called by muse, mutect2, varscan2
- PMEL | c.448_451del p.V150Mfs*13 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- COL6A6 | c.5253C>T p.C1751= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1385687797, COSV100650845; called by muse, varscan2
- KIF2C | c.378G>A p.E126= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV64764864; called by muse, mutect2, varscan2
- MMP24 | c.1038G>A p.R346= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs1251180750, COSV55771048; called by muse, mutect2, varscan2
- SLC18A1 | c.189C>T p.L63= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs202140673, COSV52348580; called by muse, mutect2, varscan2
- SLC5A11 | c.1998C>T p.C666= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs777534080, COSV61741927; called by muse, mutect2, varscan2
- TTC30A | c.1966T>C p.L656= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100826228; called by muse, mutect2, varscan2
- TUBA8 | c.565C>T p.L189= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs921226473, COSV57813333; called by muse, mutect2
- UBR4 | c.11688G>A p.L3896= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV64392334; called by muse, mutect2, varscan2
- WWC1 | c.3231C>T p.L1077= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99515776; called by muse, mutect2, varscan2
